Somatic mutation profile of tumor specimen ALCH-AEQU-TTP1-A (aliquot ALCH-AEQU-TTP1-A-1-0-D-A612-36) from ALCHEMIST case ALCH-AEQU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,248 days).
Specimen ALCH-AEQU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 080b3b33-451c-4006-8c21-2beb7f49eaa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEQU-NB1-A (Blood Derived Normal), aliquot ALCH-AEQU-NB1-A-1-0-D-A612-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbdfc8c3-dd21-4c03-8356-76354d7cd1f7

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, Nonsense Mutation 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP1CB | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 19/372 reads (5%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.001); catalogued as rs1250549046; called by muse, mutect2
- ADNP | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- APLF | c.1340A>G p.N447S | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CIITA | c.2790C>A p.D930E | Missense Mutation (SNP) | VAF 43/1418 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2
- HACD3 | c.655A>G p.I219V | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2
- KIF16B | c.2942G>T p.R981L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAP10 | c.1805C>A p.S602* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- RASSF4 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SAMD9 | c.2316A>C p.E772D | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2
- SPART | c.1017G>T p.W339C | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- STX5 | c.295A>C p.K99Q | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); called by muse, mutect2
- TTN | c.13714C>T p.H4572Y (on ENST00000591111; = p.H3645Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/202 reads (5%) | PolyPhen benign (0.161); called by muse, mutect2
- UBE2E1 | c.513_514del p.Q172Vfs*9 | Frame Shift Del (DEL) | VAF 18/195 reads (9%) | called by mutect2, pindel
- ZNF410 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 30/722 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- RFFL | c.345C>A p.L115= | Silent (SNP) | VAF 40/405 reads (10%) | called by muse, mutect2, varscan2
- EIPR1 | c.259+19092T>G | Intron (SNP) | VAF 16/533 reads (3%) | called by muse, mutect2
- MANBAL | c.150+908T>A | Intron (SNP) | VAF 12/299 reads (4%) | called by muse, mutect2
- SEPTIN9 | c.722-36603C>T | Intron (SNP) | VAF 3/37 reads (8%) | catalogued as rs1440997083, COSV61204726; called by muse, mutect2
